Somatic mutation profile of tumor specimen TCGA-QH-A65Z-01A (aliquot TCGA-QH-A65Z-01A-11D-A29Q-08) from TCGA case TCGA-QH-A65Z, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 54.5 years (19,921 days).
Specimen TCGA-QH-A65Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6547c575-172b-4289-b1ad-d1873222a70f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A65Z-10A (Blood Derived Normal), aliquot TCGA-QH-A65Z-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74fc5fa4-83d2-41f0-a505-52ccc74b1f72

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Frame Shift Del 5, Translation Start Site 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SDHA | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1061517, CM000423, CM165649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCE1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs201368309, COSV56847179; called by muse, mutect2, varscan2
- ACACB | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV58134664; called by muse, mutect2, varscan2
- ACSF3 | c.1025A>G p.K342R | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58078456; called by muse, mutect2, varscan2
- ARRDC5 | c.691C>G p.Q231E (on ENST00000381781; = p.Q217E on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV67787979; called by muse, mutect2, varscan2
- CNNM1 | c.2075A>G p.N692S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV63201629; called by muse, mutect2, varscan2
- ECT2 | c.1723C>T p.L575F (on ENST00000392692 / NM_001349098.2; = p.L544F on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51688836; called by muse, mutect2, varscan2
- EXTL1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs749852115, COSV65337557; called by muse, mutect2, varscan2
- FAM20A | c.1559G>C p.S520T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV56836716; called by muse, mutect2
- FZD7 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53809416; called by muse, mutect2, varscan2
- MED24 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62418636; called by muse, mutect2, varscan2
- MOV10L1 | c.441A>T p.E147D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV53171375; called by muse, mutect2, varscan2
- PPP1R13L | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV62908496; called by muse, mutect2, varscan2
- SVEP1 | c.5302T>C p.Y1768H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.376); catalogued as rs569537895, COSV52835608; called by muse, mutect2, varscan2
- TACR3 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV59201517; called by muse, mutect2, varscan2
- CIC | c.3831_3832del p.V1278Pfs*65 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | called by pindel, varscan2
- CTNNB1 | c.1461del p.H488Tfs*19 | Frame Shift Del (DEL) | VAF 89/272 reads (33%) | called by mutect2, pindel, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- PRAG1 | c.1106_1108del p.M369del | In Frame Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- RBBP6 | c.653dup p.Y218* | Nonsense Mutation (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- SLC1A7 | c.1680_1681del p.*561Sfs*41 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- USP34 | c.10428_10447delinsC p.L3477* | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by pindel, varscan2*
- ZACN | c.245_246dup p.S83Pfs*58 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- G0S2 | c.276C>T p.G92= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV65433140; called by muse, mutect2, varscan2
- ITSN1 | c.2535G>A p.T845= | Silent (SNP) | VAF 43/153 reads (28%) | catalogued as rs763031843, COSV66083045; called by muse, mutect2, varscan2
- LAMA5 | c.8616C>T p.D2872= | Silent (SNP) | VAF 73/166 reads (44%) | catalogued as rs187988761, COSV53358581; called by muse, mutect2, varscan2
- PHF3 | c.5640C>G p.G1880= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV50319006; called by muse, mutect2
- RYR2 | c.13899C>T p.L4633= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs1057523875, COSV63685611; ClinVar: likely benign; called by muse, mutect2
- SLC26A4 | c.474C>T p.D158= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV55915305; called by muse, mutect2
- XPNPEP2 | c.288A>T p.T96= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV64367923; called by muse, mutect2
